Somatic mutation profile of cancer-model specimen HCM-CSHL-0636-C02-85A (3D Organoid, passage 9; aliquot HCM-CSHL-0636-C02-85A-01D-A85C-36), derived from the primary tumor of HCMI case HCM-CSHL-0636-C02, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Mouth, NOS; Tumor grade: G3.
Specimen HCM-CSHL-0636-C02-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 9.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 925f4192-9297-445e-a96b-e8995e876732.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0636-C02-10A (Blood Derived Normal), aliquot HCM-CSHL-0636-C02-10A-01D-A85C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4d11b671-cff0-4d58-89e8-42bc673f5e28

The open-access MAF lists 164 somatic variants for this specimen: 122 protein-altering or splice-affecting, 36 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 106, Silent 36, Nonsense Mutation 9, Intron 4, Frame Shift Ins 2, Splice Region 2, Splice Site 2, 3'Flank 1, 5'UTR 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 1015/1018 reads (100%) | hotspot (GDC flag); catalogued as rs121913388, CM014695, COSV58682746, COSV58721651; ClinVar: risk factor / likely pathogenic; called by muse, varscan2
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 100/489 reads (20%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 694/694 reads (100%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by muse, varscan2
- A2M | c.1906G>A p.D636N | Missense Mutation (SNP) | VAF 79/479 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV59385018; called by muse, mutect2, varscan2
- ACTN2 | c.1370G>A p.R457H | Missense Mutation (SNP) | VAF 398/399 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs781559530, COSV63971955; called by muse, mutect2, varscan2
- ADAM29 | c.2216C>T p.S739F | Missense Mutation (SNP) | VAF 182/521 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.228); catalogued as COSV63667165; called by muse, mutect2, varscan2
- ANKLE1 | c.1409C>T p.T470M (on ENST00000394458; = p.T416M on NM_152363.6) | Missense Mutation (SNP) | VAF 160/335 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760470646, COSV63919953; called by muse, mutect2, varscan2
- CLDN23 | c.575G>A p.R192H | Missense Mutation (SNP) | VAF 274/606 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs373434191; called by muse, varscan2
- CWF19L2 | c.2552G>C p.G851A | Missense Mutation (SNP) | VAF 20/297 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV56512775; called by muse, mutect2
- DCT | c.1343C>T p.S448L | Missense Mutation (SNP) | VAF 158/460 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV100986235; called by muse, varscan2
- DNAH5 | c.7532G>A p.R2511Q | Missense Mutation (SNP) | VAF 360/1578 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs1391746135; called by muse, varscan2
- DUSP4 | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 292/592 reads (49%) | SIFT tolerated (0.51); PolyPhen benign (0.196); catalogued as COSV99529574; called by muse, mutect2, varscan2
- EPB41L1 | c.1289G>A p.S430N | Missense Mutation (SNP) | VAF 156/706 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1429457585; called by muse, varscan2
- EPB41L2 | c.1589C>T p.T530I | Missense Mutation (SNP) | VAF 26/604 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as rs773976530; called by muse, mutect2
- FAM178B | c.649C>T p.R217* | Nonsense Mutation (SNP) | VAF 167/564 reads (30%) | catalogued as rs746051795, COSV100014585; called by muse, varscan2
- FGD3 | c.1560C>T p.L520= | Splice Region (SNP) | VAF 128/254 reads (50%) | catalogued as rs546814653, COSV100490537; called by muse, mutect2, varscan2
- FKBP15 | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 186/782 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.359); catalogued as rs752713915; called by muse, varscan2
- FKBP1B | c.268G>A p.G90S | Missense Mutation (SNP) | VAF 219/971 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as rs1401529234; called by muse, mutect2, varscan2
- FSIP2 | c.20668C>T p.Q6890* | Nonsense Mutation (SNP) | VAF 119/433 reads (27%) | catalogued as rs1476585630, COSV58092896; called by muse, mutect2, varscan2
- GALC | c.20C>T p.S7L | Missense Mutation (SNP) | VAF 150/607 reads (25%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.014); catalogued as COSV54329902; called by muse, varscan2
- GCC2 | c.160G>C p.E54Q | Missense Mutation (SNP) | VAF 58/284 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59174602; called by muse, mutect2, varscan2
- HSF1 | c.1088C>G p.S363C | Missense Mutation (SNP) | VAF 124/803 reads (15%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.549); catalogued as rs1554844982; called by mutect2, varscan2
- IDO2 | c.850C>T p.R284C (on ENST00000389060; = p.R297C on NM_194294.2) | Missense Mutation (SNP) | VAF 138/561 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs765222349, COSV58423342; called by muse, mutect2, varscan2
- KLHL21 | c.1615G>C p.A539P | Missense Mutation (SNP) | VAF 260/980 reads (27%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.655); catalogued as COSV100887299; called by muse, varscan2
- LAMB1 | c.1384C>T p.P462S | Missense Mutation (SNP) | VAF 100/706 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.612); catalogued as rs267601230; called by muse, mutect2, varscan2
- LMBR1L | c.1167G>T p.M389I | Missense Mutation (SNP) | VAF 182/696 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.056); catalogued as COSV99918936; called by muse, varscan2
- MED26 | c.77G>A p.R26Q | Missense Mutation (SNP) | VAF 150/316 reads (47%) | SIFT tolerated (0.35); PolyPhen benign (0.151); catalogued as rs575658283, COSV54663050, COSV99660047; called by muse, mutect2, varscan2
- MYH8 | c.4632G>T p.Q1544H | Missense Mutation (SNP) | VAF 94/466 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV67962949; called by muse, varscan2
- OR14J1 | c.532G>T p.D178Y | Missense Mutation (SNP) | VAF 164/519 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs1228813149, COSV65845587; called by muse, mutect2, varscan2
- OR7A5 | c.592G>A p.V198M | Missense Mutation (SNP) | VAF 105/219 reads (48%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.34); catalogued as rs1372678343; called by muse, mutect2, varscan2
- P3H3 | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 201/844 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); catalogued as rs1555121194; called by muse, mutect2, varscan2
- PCDHA8 | c.1450G>A p.A484T | Missense Mutation (SNP) | VAF 658/1034 reads (64%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.23); catalogued as COSV65337680, COSV65339512; called by muse, varscan2
- PCDHB2 | c.122C>T p.T41M | Missense Mutation (SNP) | VAF 405/616 reads (66%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.41); catalogued as rs1554271108, COSV52034436; called by muse, mutect2, varscan2
- PDE7B | c.1151C>T p.P384L | Missense Mutation (SNP) | VAF 186/640 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1045159121; called by muse, varscan2
- PIGG | c.1728G>C p.Q576H (on ENST00000453061 / NM_001127178.3; = p.Q568H on NM_017733.4) | Missense Mutation (SNP) | VAF 148/457 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV99574010; called by muse, mutect2, varscan2
- PKHD1 | c.4277C>T p.S1426L | Missense Mutation (SNP) | VAF 227/699 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs771702541, COSV61874668, COSV61885805, COSV61886900; ClinVar: uncertain significance; called by muse, varscan2
- PLEKHM3 | c.2240T>C p.L747P | Missense Mutation (SNP) | VAF 372/530 reads (70%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as rs1464506011; called by muse, varscan2
- POLM | c.46G>C p.D16H | Missense Mutation (SNP) | VAF 224/512 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.225); catalogued as rs750258630, COSV54243070; called by muse, mutect2, varscan2
- PRSS41 | c.921G>C p.W307C | Missense Mutation (SNP) | VAF 212/928 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68786377; called by muse, varscan2
- RBM46 | c.1100G>T p.R367I | Missense Mutation (SNP) | VAF 132/544 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.034); catalogued as COSV55977274; called by muse, mutect2, varscan2
- RESF1 | c.1389G>C p.E463D | Missense Mutation (SNP) | VAF 138/710 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.012); catalogued as COSV57020874; called by muse, mutect2, varscan2
- RIOK3 | c.143A>G p.Q48R | Missense Mutation (SNP) | VAF 131/266 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs1228868020; called by muse, mutect2, varscan2
- RP1 | c.364C>T p.R122W | Missense Mutation (SNP) | VAF 246/1676 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV55118474; called by muse, varscan2
- RPS26 | c.64C>G p.R22G | Missense Mutation (SNP) | VAF 144/703 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.047); catalogued as rs762701251; called by muse, mutect2, varscan2
- RSRC2 | c.481G>C p.E161Q | Missense Mutation (SNP) | VAF 253/741 reads (34%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.07); catalogued as COSV59206464; called by muse, varscan2
- RUSC1 | c.1064C>T p.S355L | Missense Mutation (SNP) | VAF 315/966 reads (33%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as rs199994966, COSV52740855, COSV52740954; called by muse, varscan2
- SCN1A | c.1733G>C p.R578T | Missense Mutation (SNP) | VAF 152/556 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.905); catalogued as COSV57660982; called by muse, varscan2
- SEC23IP | c.20A>C p.N7T | Missense Mutation (SNP) | VAF 186/388 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.196); catalogued as rs1224047952; called by muse, varscan2
- SLC26A5 | c.1196G>T p.R399L | Missense Mutation (SNP) | VAF 97/569 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59700903; called by mutect2, varscan2
- SLC27A2 | c.905G>A p.R302K | Missense Mutation (SNP) | VAF 310/442 reads (70%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.976); catalogued as COSV51062675; called by muse, mutect2, varscan2
- SLC6A7 | c.737C>T p.T246M | Missense Mutation (SNP) | VAF 157/500 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs569505476; called by muse, mutect2, varscan2
- SOGA3 | c.1249G>C p.E417Q | Missense Mutation (SNP) | VAF 240/772 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs371330401, COSV64106260; called by muse, varscan2
- SP140L | c.1511C>T p.A504V | Missense Mutation (SNP) | VAF 56/304 reads (18%) | SIFT tolerated (0.46); PolyPhen benign (0.041); catalogued as rs778323974, COSV99706680; called by muse, varscan2
- SP5 | c.1024G>A p.E342K | Missense Mutation (SNP) | VAF 339/1054 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64623625; called by muse, varscan2
- SPTBN2 | c.5692G>A p.A1898T | Missense Mutation (SNP) | VAF 296/864 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as rs759505522, COSV59447181, COSV59451981; ClinVar: uncertain significance; called by muse, varscan2
- TAOK3 | c.753G>C p.R251S | Missense Mutation (SNP) | VAF 94/351 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.803); catalogued as COSV66827371; called by muse, mutect2, varscan2
- TMC4 | c.457G>T p.G153W (on ENST00000617472 / NM_001145303.3; = p.G147W on NM_144686.4) | Missense Mutation (SNP) | VAF 355/996 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs920641700, COSV55476147; called by muse, mutect2, varscan2
- TOX | c.404T>C p.I135T | Missense Mutation (SNP) | VAF 88/484 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as rs764851208; called by muse, mutect2, varscan2
- TP53 | c.550G>C p.D184H | Missense Mutation (SNP) | VAF 130/660 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); catalogued as CD1511133, CM1410330, COSV52688642, COSV52876364, COSV52980443, COSV53771626; called by muse, varscan2
- TPRX1 | c.557C>T p.P186L | Missense Mutation (SNP) | VAF 680/1500 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as rs1441035397; called by muse, varscan2
- ADGRA2 | c.2966C>T p.S989L | Missense Mutation (SNP) | VAF 212/1027 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- AKR1C4 | c.257G>A p.W86* | Nonsense Mutation (SNP) | VAF 110/362 reads (30%) | called by muse, mutect2, varscan2
- ALG5 | c.778T>A p.F260I | Missense Mutation (SNP) | VAF 97/348 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- APOL2 | c.631G>C p.D211H | Missense Mutation (SNP) | VAF 417/619 reads (67%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- ATP1A1 | c.483C>G p.F161L | Missense Mutation (SNP) | VAF 102/354 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); called by muse, varscan2
- ATP6V1C1 | c.727G>C p.E243Q | Missense Mutation (SNP) | VAF 110/589 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- C10orf88 | c.1065A>C p.E355D | Missense Mutation (SNP) | VAF 141/294 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.009); called by muse, varscan2
- C7 | c.2515G>T p.A839S | Missense Mutation (SNP) | VAF 38/614 reads (6%) | SIFT tolerated (0.76); PolyPhen benign (0.015); called by muse, mutect2
- CCDC154 | c.1438-40_1438-1del p.X480_splice | Splice Site (DEL) | VAF 44/366 reads (12%) | called by mutect2, pindel
- CNGA1 | c.1774G>A p.E592K | Missense Mutation (SNP) | VAF 162/552 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.05); called by muse, varscan2
- COL14A1 | c.4525A>G p.S1509G | Missense Mutation (SNP) | VAF 40/777 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); called by muse, mutect2
- CREB3L4 | c.326C>G p.S109C | Missense Mutation (SNP) | VAF 177/547 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- CSTF2T | c.765G>C p.Q255H | Missense Mutation (SNP) | VAF 166/655 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ECT2 | c.863A>G p.N288S (on ENST00000392692 / NM_001349098.2; = p.N257S on NM_018098.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 167/330 reads (51%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- EHD2 | c.904C>G p.R302G | Missense Mutation (SNP) | VAF 136/746 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.401); called by muse, varscan2
- EPB41L2 | c.2734G>C p.D912H | Missense Mutation (SNP) | VAF 146/456 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, varscan2
- ERN1 | c.1087+1G>A p.X363_splice | Splice Site (SNP) | VAF 197/292 reads (67%) | called by muse, mutect2, varscan2
- FAM189A1 | c.341C>G p.S114C | Missense Mutation (SNP) | VAF 22/533 reads (4%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); called by muse, mutect2
- FAM193A | c.1519C>T p.L507F | Missense Mutation (SNP) | VAF 182/524 reads (35%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); called by muse, varscan2
- FAM20A | c.560A>T p.D187V | Missense Mutation (SNP) | VAF 53/458 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); called by muse, varscan2
- FOXI1 | c.961T>A p.S321T | Missense Mutation (SNP) | VAF 292/950 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, varscan2
- GMDS | c.322C>T p.L108F | Missense Mutation (SNP) | VAF 192/384 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, varscan2
- GOLGA6L22 | c.113A>C p.K38T | Missense Mutation (SNP) | VAF 170/763 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.1128G>T p.V376= | Splice Region (SNP) | VAF 53/724 reads (7%) | called by muse, mutect2
- KIF5C | c.1051G>C p.E351Q | Missense Mutation (SNP) | VAF 123/489 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.6); called by muse, mutect2, varscan2
- MAN2B2 | c.558G>T p.E186D | Missense Mutation (SNP) | VAF 126/380 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by muse, varscan2
- MOCS1 | c.542C>T p.T181I | Missense Mutation (SNP) | VAF 176/520 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NAV3 | c.4467T>A p.F1489L | Missense Mutation (SNP) | VAF 88/253 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- NRK | c.2271T>A p.D757E | Missense Mutation (SNP) | VAF 84/205 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); called by muse, mutect2, varscan2
- OR4P4 | c.73T>C p.C25R | Missense Mutation (SNP) | VAF 121/493 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); called by muse, mutect2, varscan2
- PCDHGB7 | c.2317C>T p.H773Y | Missense Mutation (SNP) | VAF 180/453 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PDHX | c.320A>G p.D107G | Missense Mutation (SNP) | VAF 210/212 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, varscan2
- PDZD3 | c.910G>A p.E304K (on ENST00000531114; = p.E224K on NM_024791.4) | Missense Mutation (SNP) | VAF 213/524 reads (41%) | SIFT tolerated (0.38); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- PLD6 | c.268G>A p.A90T | Missense Mutation (SNP) | VAF 314/1348 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); called by muse, varscan2
- RABAC1 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 414/844 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.267); called by muse, mutect2, varscan2
- RADIL | c.2188C>G p.Q730E | Missense Mutation (SNP) | VAF 207/1058 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- REV3L | c.230C>G p.S77C | Missense Mutation (SNP) | VAF 172/566 reads (30%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.873); called by muse, varscan2
- RGMB | c.667dup p.H223Pfs*3 (on ENST00000513185 / NM_001366508.1; = p.H264Pfs*3 on NM_001012761.3 and 3 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 146/265 reads (55%) | called by mutect2, pindel, varscan2
- RSRC2 | c.73G>C p.E25Q | Missense Mutation (SNP) | VAF 174/542 reads (32%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.402); called by muse, varscan2
- SIGLEC7 | c.840C>G p.S280R | Missense Mutation (SNP) | VAF 208/917 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SLC35F4 | c.56G>A p.R19Q | Missense Mutation (SNP) | VAF 165/425 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- SLU7 | c.1083dup p.E362Rfs*27 | Frame Shift Ins (INS) | VAF 89/310 reads (29%) | called by mutect2, pindel, varscan2
- SMG8 | c.1915G>A p.E639K | Missense Mutation (SNP) | VAF 93/312 reads (30%) | SIFT tolerated (0.4); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SNX9 | c.1189C>T p.Q397* | Nonsense Mutation (SNP) | VAF 99/342 reads (29%) | called by muse, varscan2
- STX12 | c.818A>T p.Y273F | Missense Mutation (SNP) | VAF 195/303 reads (64%) | SIFT tolerated (0.7); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- STX18 | c.923A>G p.N308S | Missense Mutation (SNP) | VAF 115/374 reads (31%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- STYXL1 | c.139G>A p.V47M | Missense Mutation (SNP) | VAF 294/296 reads (99%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); called by muse, varscan2
- SYNGR2 | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 326/1032 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.025); called by muse, varscan2
- TNFRSF8 | c.607G>C p.E203Q | Missense Mutation (SNP) | VAF 214/732 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- TRAF5 | c.1003C>G p.Q335E | Missense Mutation (SNP) | VAF 146/298 reads (49%) | SIFT tolerated (0.38); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- TRPA1 | c.3018T>A p.Y1006* | Nonsense Mutation (SNP) | VAF 153/525 reads (29%) | called by muse, mutect2, varscan2
- TTN | c.99661C>A p.P33221T (on ENST00000591111; = p.P25797T on NM_003319.4) | Missense Mutation (SNP) | VAF 177/605 reads (29%) | PolyPhen benign (0); called by muse, mutect2, varscan2
- UTRN | c.916G>A p.E306K | Missense Mutation (SNP) | VAF 180/491 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.725); called by muse, mutect2, varscan2
- VCPIP1 | c.2275C>T p.P759S | Missense Mutation (SNP) | VAF 136/1046 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.27); called by muse, mutect2, varscan2
- WDR12 | c.673G>A p.D225N | Missense Mutation (SNP) | VAF 97/327 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- ZBTB38 | c.1233C>G p.N411K | Missense Mutation (SNP) | VAF 274/620 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.158); called by muse, varscan2
- ZFHX4 | c.7048G>A p.E2350K | Missense Mutation (SNP) | VAF 422/648 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- ZMAT1 | c.420T>G p.Y140* | Nonsense Mutation (SNP) | VAF 24/488 reads (5%) | called by muse, mutect2
- ZNF286A | c.394G>C p.E132Q | Missense Mutation (SNP) | VAF 182/892 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.088); called by muse, varscan2
- ZNF287 | c.97G>C p.E33Q | Missense Mutation (SNP) | VAF 166/704 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.313); called by muse, varscan2
- ZNF548 | c.194C>T p.S65F | Missense Mutation (SNP) | VAF 180/1083 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- ZZZ3 | c.2561C>G p.S854* | Nonsense Mutation (SNP) | VAF 96/296 reads (32%) | called by muse, varscan2
- AP1G2 | c.2244C>G p.L748= | Silent (SNP) | VAF 139/139 reads (100%) | called by muse, mutect2, varscan2
- C10orf143 | c.201G>A p.R67= | Silent (SNP) | VAF 188/382 reads (49%) | called by muse, varscan2
- C20orf194 | c.1968C>T p.I656= | Silent (SNP) | VAF 151/509 reads (30%) | called by muse, mutect2, varscan2
- CEP250 | c.6426T>C p.D2142= | Silent (SNP) | VAF 460/819 reads (56%) | called by muse, mutect2, varscan2
- CIITA | c.870C>T p.F290= | Silent (SNP) | VAF 289/1202 reads (24%) | catalogued as rs546955314, COSV60860093; called by muse, varscan2
- COG7 | c.1762C>T p.L588= | Silent (SNP) | VAF 286/638 reads (45%) | called by muse, varscan2
- CORO2A | c.78C>T p.Y26= | Silent (SNP) | VAF 428/880 reads (49%) | catalogued as rs150682499; called by muse, varscan2
- CPVL | c.546A>G p.A182= | Silent (SNP) | VAF 112/460 reads (24%) | called by muse, varscan2
- ECI1 | c.63C>T p.L21= | Silent (SNP) | VAF 262/1128 reads (23%) | called by muse, varscan2
- FAM193A | c.1638C>T p.F546= | Silent (SNP) | VAF 121/371 reads (33%) | catalogued as COSV61197116; called by muse, mutect2, varscan2
- FAM193A | c.1827C>T p.V609= | Silent (SNP) | VAF 165/509 reads (32%) | called by muse, mutect2, varscan2
- FFAR3 | c.927G>A p.L309= | Silent (SNP) | VAF 174/885 reads (20%) | called by muse, varscan2
- FGFR3 | c.241C>T p.L81= | Silent (SNP) | VAF 340/905 reads (38%) | called by muse, mutect2, varscan2
- FGGY | c.1452C>G p.S484= | Silent (SNP) | VAF 113/388 reads (29%) | catalogued as COSV58026973, COSV58046049; called by muse, mutect2, varscan2
- GRINA | c.1009C>T p.L337= | Silent (SNP) | VAF 192/1062 reads (18%) | called by muse, varscan2
- H2BC18 | c.222C>T p.I74= | Silent (SNP) | VAF 218/743 reads (29%) | catalogued as rs782575950, COSV100516145, COSV58944587; called by muse, varscan2
- HDLBP | c.3498C>T p.S1166= | Silent (SNP) | VAF 159/500 reads (32%) | catalogued as rs765201762; called by muse, varscan2
- KIF25 | c.501C>T p.V167= | Silent (SNP) | VAF 83/364 reads (23%) | catalogued as rs367910669; called by muse, mutect2, varscan2
- LAPTM5 | c.648C>T p.I216= | Silent (SNP) | VAF 161/476 reads (34%) | called by muse, mutect2, varscan2
- MAN2A1 | c.933C>T p.I311= | Silent (SNP) | VAF 152/529 reads (29%) | catalogued as rs367625663; called by muse, mutect2, varscan2
- MAPK8IP2 | c.1491G>A p.S497= | Silent (SNP) | VAF 324/324 reads (100%) | catalogued as rs1388168034, COSV50499075; called by muse, varscan2
- MCF2 | c.1722G>A p.V574= | Silent (SNP) | VAF 185/185 reads (100%) | catalogued as COSV100644819; called by muse, mutect2, varscan2
- NINL | c.1782A>G p.R594= | Silent (SNP) | VAF 158/1011 reads (16%) | called by muse, mutect2, varscan2
- NUMA1 | c.1188G>A p.Q396= | Silent (SNP) | VAF 537/977 reads (55%) | called by mutect2, varscan2
- P2RY13 | c.303C>T p.L101= | Silent (SNP) | VAF 158/747 reads (21%) | catalogued as COSV99853684; called by muse, varscan2
- PCDHB13 | c.1215G>C p.T405= | Silent (SNP) | VAF 121/408 reads (30%) | catalogued as rs200643533, COSV53401300; called by muse, mutect2, varscan2
- PSPC1 | c.357C>T p.F119= | Silent (SNP) | VAF 150/364 reads (41%) | catalogued as rs1392017558; called by muse, mutect2, varscan2
- PTRH1 | c.609C>T p.I203= | Silent (SNP) | VAF 236/471 reads (50%) | called by muse, varscan2
- SBK2 | c.804C>T p.A268= | Silent (SNP) | VAF 354/2049 reads (17%) | catalogued as rs1339170511; called by muse, varscan2
- SCN7A | c.2793A>C p.V931= | Silent (SNP) | VAF 196/652 reads (30%) | catalogued as COSV69273714; called by muse, varscan2
- SERPINF1 | c.1221C>T p.L407= | Silent (SNP) | VAF 158/697 reads (23%) | catalogued as COSV54616003; called by muse, mutect2, varscan2
- SIN3A | c.2493C>G p.L831= | Silent (SNP) | VAF 474/710 reads (67%) | catalogued as COSV64582670; called by muse, mutect2, varscan2
- SLC8B1 | c.1578G>A p.L526= | Silent (SNP) | VAF 134/476 reads (28%) | called by muse, varscan2
- TNIP1 | c.897C>T p.A299= | Silent (SNP) | VAF 200/582 reads (34%) | catalogued as rs755163502; called by muse, varscan2
- ZNF577 | c.1311A>T p.V437= | Silent (SNP) | VAF 93/716 reads (13%) | called by muse, mutect2, varscan2
- ZSCAN5B | c.879G>A p.L293= | Silent (SNP) | VAF 256/1383 reads (19%) | catalogued as COSV61999641; called by muse, mutect2, varscan2
- LCORL | chr4:17876104 G>A | 3'Flank (SNP) | VAF 105/308 reads (34%) | called by muse, mutect2, varscan2
- LMNA | c.357-717G>A | Intron (SNP) | VAF 166/411 reads (40%) | catalogued as rs771469778; called by muse, varscan2
- MACF1 | c.372+1811G>A | Intron (SNP) | VAF 160/536 reads (30%) | called by muse, mutect2, varscan2
- MASP1 | c.1303+4920G>A | Intron (SNP) | VAF 124/534 reads (23%) | catalogued as rs748318112; called by muse, mutect2
- OTUD6B | c.-33C>T | 5'UTR (SNP) | VAF 165/1075 reads (15%) | called by muse, mutect2, varscan2
- UNC13B | c.761+6760G>T | Intron (SNP) | VAF 90/315 reads (29%) | called by muse, mutect2, varscan2
